Somatic mutation profile of tumor specimen TCGA-36-2552-01A (aliquot TCGA-36-2552-01A-01D-1526-09) from TCGA case TCGA-36-2552, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIC; Tumor grade: G3; Age at diagnosis: 64.0 years (23,379 days).
Specimen TCGA-36-2552-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bd60b64f-847c-44f4-a903-cd30237b68c3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-36-2552-10A (Blood Derived Normal), aliquot TCGA-36-2552-10A-01D-1526-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/07709483-5b5d-4d1f-8b2b-aa6f77df9549

The open-access MAF lists 66 somatic variants for this specimen: 43 protein-altering or splice-affecting, 20 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, Silent 20, 5'UTR 2, Nonsense Mutation 2, RNA 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.574C>T p.Q192* | Nonsense Mutation (SNP) | VAF 320/330 reads (97%) | hotspot (GDC flag); catalogued as rs866380588, COSV52660737, COSV52978302; ClinVar: pathogenic; called by muse, mutect2, varscan2
- B3GAT1 | c.655G>A p.V219I | Missense Mutation (SNP) | VAF 28/107 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1473343688, COSV56999995; called by muse, mutect2, varscan2
- CALCR | c.1357G>A p.D453N (on ENST00000649521 / NM_001164737.2; = p.D437N on NM_001742.4) | Missense Mutation (SNP) | VAF 84/160 reads (53%) | SIFT tolerated (0.13); PolyPhen benign (0.013); catalogued as rs530931616, COSV64008410; called by muse, mutect2
- CCDC81 | c.1136A>T p.E379V (on ENST00000445632 / NM_001156474.2; = p.E289V on NM_021827.4) | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.835); catalogued as COSV53580847; called by muse, varscan2
- CHD5 | c.3260A>T p.N1087I | Missense Mutation (SNP) | VAF 55/198 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52422652; called by muse, mutect2, varscan2
- DCHS1 | c.2932C>T p.R978C | Missense Mutation (SNP) | VAF 21/35 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs201160085; called by muse, mutect2, varscan2
- DNAH5 | c.2608C>T p.H870Y | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV54245746; called by muse, mutect2, varscan2
- EEF2KMT | c.211C>T p.R71W | Missense Mutation (SNP) | VAF 46/342 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs537216471, COSV69863433, COSV69863495; called by muse, mutect2, varscan2
- FBN3 | c.5709C>G p.C1903W | Missense Mutation (SNP) | VAF 76/368 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54469592; called by muse, mutect2, varscan2
- GOLGB1 | c.6368T>G p.L2123R | Missense Mutation (SNP) | VAF 24/227 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV61469661; called by muse, mutect2, varscan2
- HK3 | c.664G>A p.D222N | Missense Mutation (SNP) | VAF 179/278 reads (64%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs764008081, COSV52843464; called by muse, mutect2, varscan2
- HS3ST2 | c.614G>A p.R205Q | Missense Mutation (SNP) | VAF 109/353 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54462844, COSV99757710; called by muse, mutect2, varscan2
- KDR | c.2510G>A p.G837D | Missense Mutation (SNP) | VAF 36/132 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55773404; called by muse, mutect2, varscan2
- KPNB1 | c.2305T>C p.Y769H | Missense Mutation (SNP) | VAF 97/228 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as COSV51599811; called by muse, mutect2, varscan2
- LGALS8 | c.698G>A p.R233H (on ENST00000341872; = p.R275H on NM_006499.4) | Missense Mutation (SNP) | VAF 42/271 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.475); catalogued as rs369820574; called by muse, mutect2, varscan2
- LOXL3 | c.731A>G p.H244R | Missense Mutation (SNP) | VAF 23/35 reads (66%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs1257799499, COSV51211929; called by muse, mutect2, varscan2
- MAP2 | c.13C>T p.R5W | Missense Mutation (SNP) | VAF 61/368 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.847); catalogued as rs138782038, COSV99561968; called by muse, mutect2, varscan2
- MOS | c.206G>C p.G69A | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100322885, COSV61336839; called by muse, mutect2, varscan2
- MPP1 | c.311T>G p.M104R | Missense Mutation (SNP) | VAF 96/106 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV65728647; called by muse, mutect2
- MYO6 | c.1618G>T p.D540Y | Missense Mutation (SNP) | VAF 70/409 reads (17%) | SIFT tolerated (1); PolyPhen probably damaging (0.999); catalogued as COSV100889301, COSV64120759; called by muse, mutect2, varscan2
- PAQR3 | c.60G>A p.W20* | Nonsense Mutation (SNP) | VAF 77/111 reads (69%) | catalogued as COSV55011372; called by muse, mutect2, varscan2
- PCDH7 | c.2317G>A p.D773N | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV62337307, COSV62337513; called by muse, mutect2, varscan2
- PIMREG | c.37C>A p.R13S | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.468); catalogued as COSV51471719; called by muse, mutect2, varscan2
- PODN | c.325C>T p.P109S (on ENST00000395871; = p.P61S on NM_153703.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.037); catalogued as COSV57016373; called by muse, mutect2, varscan2
- PRKD1 | c.1175C>G p.A392G | Missense Mutation (SNP) | VAF 122/346 reads (35%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs1216779122, COSV59581377; called by muse, mutect2, varscan2
- PRPF38B | c.1314G>C p.R438S | Missense Mutation (SNP) | VAF 25/115 reads (22%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.003); catalogued as COSV64223880; called by muse, mutect2, varscan2
- RBM46 | c.821C>G p.A274G | Missense Mutation (SNP) | VAF 40/182 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.601); catalogued as COSV55979680, COSV55981235; called by muse, mutect2, varscan2
- SCAF1 | c.2320G>T p.D774Y | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.663); catalogued as COSV62184655; called by muse, mutect2, varscan2
- SFXN4 | c.326G>T p.R109L | Missense Mutation (SNP) | VAF 118/736 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57460865; called by muse, mutect2, varscan2
- SH3BP5L | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 82/450 reads (18%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.899); catalogued as COSV63539755; called by muse, mutect2, varscan2
- SMAP1 | c.326C>G p.P109R | Missense Mutation (SNP) | VAF 42/206 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57643514, COSV57645105; called by muse, mutect2, varscan2
- TGFBR3 | c.2537C>A p.S846Y | Missense Mutation (SNP) | VAF 35/120 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53029949; called by muse, mutect2, varscan2
- TGFBR3 | c.1616G>C p.G539A | Missense Mutation (SNP) | VAF 37/153 reads (24%) | SIFT tolerated (0.93); PolyPhen benign (0.052); catalogued as COSV53029958; called by muse, mutect2, varscan2
- TGM5 | c.1771G>C p.D591H (on ENST00000220420 / NM_201631.4; = p.D509H on NM_004245.4) | Missense Mutation (SNP) | VAF 78/232 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs771315481, COSV55011701; called by muse, mutect2, varscan2
- UBA6 | c.1744T>A p.L582I | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.013); catalogued as COSV59180355; called by muse, mutect2, varscan2
- USP32 | c.4543A>G p.I1515V | Missense Mutation (SNP) | VAF 131/259 reads (51%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.97); catalogued as rs776803500, COSV56275229; called by muse, mutect2, varscan2
- VPS13C | c.8852G>A p.G2951D (on ENST00000644861 / NM_020821.3; = p.G2908D on NM_017684.5) | Missense Mutation (SNP) | VAF 47/138 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs750910296, COSV51419047; called by muse, mutect2, varscan2
- ZKSCAN4 | c.739G>T p.D247Y | Missense Mutation (SNP) | VAF 98/678 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV66023924; called by muse, mutect2, varscan2
- ZNF322 | c.149A>G p.Q50R | Missense Mutation (SNP) | VAF 66/532 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV70652208; called by muse, mutect2, varscan2
- ZNF638 | c.5515C>A p.L1839I | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.34); PolyPhen benign (0.202); catalogued as rs752032123, COSV100039134, COSV52494371; called by muse, mutect2, varscan2
- ZSCAN30 | c.1176G>C p.K392N | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV99735034; called by muse, mutect2
- KIR2DS4 | c.82A>C p.K28Q | Missense Mutation (SNP) | VAF 18/342 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.947); called by muse, mutect2
- RESF1 | c.4401_4404dup p.V1469Lfs*8 | Frame Shift Ins (INS) | VAF 41/153 reads (27%) | called by mutect2, pindel, varscan2
- ADGRF1 | c.591G>T p.S197= | Silent (SNP) | VAF 44/372 reads (12%) | catalogued as COSV51947233; called by muse, mutect2, varscan2
- ADPRHL1 | c.138C>T p.L46= | Silent (SNP) | VAF 70/433 reads (16%) | catalogued as rs148683938; called by muse, mutect2, varscan2
- ASXL1 | c.2754C>T p.H918= | Silent (SNP) | VAF 43/178 reads (24%) | catalogued as rs529527086, COSV60118028; called by muse, mutect2, varscan2
- CFAP70 | c.381G>A p.L127= | Silent (SNP) | VAF 54/387 reads (14%) | catalogued as COSV60286061; called by muse, mutect2, varscan2
- CKAP4 | c.342C>A p.L114= | Silent (SNP) | VAF 8/10 reads (80%) | catalogued as rs1279795942, COSV65173134; called by mutect2, varscan2
- COL3A1 | c.1944T>C p.G648= | Silent (SNP) | VAF 21/114 reads (18%) | catalogued as COSV58594808; called by muse, mutect2, varscan2
- DEFB110 | c.198G>A p.Q66= | Silent (SNP) | VAF 61/348 reads (18%) | catalogued as COSV64484808; called by muse, mutect2, varscan2
- EIF4G1 | c.1254C>T p.V418= (on ENST00000346169 / NM_198241.3; = p.V222= on NM_004953.5) | Silent (SNP) | VAF 218/467 reads (47%) | catalogued as COSV59993136; called by muse, mutect2, varscan2
- HBS1L | c.2007C>T p.Y669= | Silent (SNP) | VAF 82/272 reads (30%) | catalogued as rs567806855, COSV63202524; called by muse, mutect2, varscan2
- KIFC1 | c.1449C>T p.G483= | Silent (SNP) | VAF 17/106 reads (16%) | catalogued as rs1271634529, COSV100997116; called by muse, mutect2
- MMP2 | c.1713C>T p.A571= | Silent (SNP) | VAF 81/178 reads (46%) | catalogued as COSV54604364; called by muse, mutect2, varscan2
- NEFM | c.612C>T p.R204= | Silent (SNP) | VAF 29/83 reads (35%) | catalogued as COSV55333842; called by muse, mutect2, varscan2
- NNT | c.360G>T p.L120= | Silent (SNP) | VAF 92/176 reads (52%) | catalogued as COSV52928614; called by muse, mutect2, varscan2
- OPCML | c.432C>T p.D144= | Silent (SNP) | VAF 73/281 reads (26%) | catalogued as rs753128145, COSV100098749, COSV59429603; called by muse, mutect2, varscan2
- PRRC2A | c.5700G>A p.Q1900= | Silent (SNP) | VAF 14/97 reads (14%) | catalogued as rs756983393, COSV52994020; called by muse, mutect2, varscan2
- SCRIB | c.678C>T p.D226= | Silent (SNP) | VAF 46/145 reads (32%) | catalogued as rs765553733, COSV57588629; called by muse, mutect2, varscan2
- SSBP4 | c.582C>T p.G194= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as rs368498567; called by muse, mutect2, varscan2
- TRAF5 | c.1419G>T p.L473= | Silent (SNP) | VAF 67/311 reads (22%) | catalogued as COSV54824263; called by muse, mutect2, varscan2
- TRIM5 | c.393A>G p.T131= | Silent (SNP) | VAF 68/233 reads (29%) | catalogued as rs1468518130, COSV59901808; called by muse, mutect2, varscan2
- VSTM2A | c.168G>A p.S56= | Silent (SNP) | VAF 21/171 reads (12%) | catalogued as rs1229335101, COSV56493571; called by muse, mutect2, varscan2
- C2orf66 | c.-2C>A | 5'UTR (SNP) | VAF 22/730 reads (3%) | catalogued as COSV100692821; called by muse, mutect2
- H2AC17 | c.-2C>T | 5'UTR (SNP) | VAF 26/135 reads (19%) | called by muse, mutect2, varscan2
- TXNRD3 | n.562G>T | RNA (SNP) | VAF 17/100 reads (17%) | catalogued as COSV67311569, COSV67312188; called by muse, mutect2, varscan2
